FM case AD12308 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Gallbladder.
https://portal.gdc.cancer.gov/cases/7a32c8cf-2c0a-44bd-81d0-0461c6d1d4df

Female, 59.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the gallbladder; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
